Somatic mutation profile of tumor specimen TCGA-A2-A1FZ-01A (aliquot TCGA-A2-A1FZ-01A-51D-A17G-09) from TCGA case TCGA-A2-A1FZ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.1 years (23,055 days).
Specimen TCGA-A2-A1FZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d528ac3c-d7c2-45b4-b1f0-ca45e0b9cf86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A1FZ-10A (Blood Derived Normal), aliquot TCGA-A2-A1FZ-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a8bcc55-4bba-44b6-b6f7-358d655615cf

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD12 | c.1785_1786del p.S596Cfs*5 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as COSV50839744; called by mutect2, varscan2
- FBXO15 | c.356C>G p.S119* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV54047589; called by muse, mutect2, varscan2
- LYSMD1 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs200029870, COSV54861179; called by muse, mutect2
- MATN2 | c.1960A>C p.I654L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54717227; called by muse, mutect2, varscan2
- MYB | c.308T>C p.V103A | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57200753; called by muse, mutect2, varscan2
- NUP107 | c.2620T>C p.C874R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV57497128; called by muse, mutect2, varscan2
- OR6X1 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as rs143796976; called by muse, mutect2, varscan2
- OSBPL9 | c.752A>T p.H251L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV61873626; called by muse, mutect2, varscan2
- PLD6 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs778989094, COSV58634378; called by muse, mutect2, varscan2
- RHOBTB1 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs777754426, COSV61958312; called by muse, mutect2, varscan2
- SCN9A | c.1766_1769del p.F589Cfs*25 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs775868908; called by mutect2, pindel, varscan2
- SEC24A | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1428227740, COSV59749045; called by muse, mutect2, varscan2
- SLF2 | c.1189A>G p.S397G | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV99489590; called by muse, mutect2
- SPP2 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99394689; called by muse, mutect2, varscan2
- TOGARAM1 | c.2167G>T p.D723Y | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV63894134; called by muse, mutect2, varscan2
- TTYH1 | c.857C>G p.T286S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56614099; called by muse, mutect2, varscan2
- ULK3 | c.1055A>G p.N352S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs753772870, COSV71348105; called by muse, mutect2, varscan2
- CNOT1 | c.6328del p.L2110Ffs*11 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- FOXA1 | c.1241dup p.L415Afs*143 | Frame Shift Ins (INS) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- LUC7L2 | c.255+3_255+6del p.X85_splice | Splice Site (DEL) | VAF 10/68 reads (15%) | called by pindel, varscan2
- FOLR1 | c.393C>T p.N131= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs61735636, COSV56616714; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMA5 | c.369C>T p.G123= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1317515334, COSV53368561; called by muse, mutect2, varscan2
- SLC6A14 | c.519T>C p.C173= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV64148177; called by muse, mutect2, varscan2
- TMPRSS9 | c.1044G>A p.P348= (on ENST00000648592; = p.P314= on NM_182973.2) | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs763755693, COSV100211626; called by muse, mutect2
- WIPI1 | c.1293+1600G>T | Intron (SNP) | VAF 11/38 reads (29%) | catalogued as COSV50931048; called by muse, mutect2, varscan2
